Somatic mutation profile of tumor specimen TCGA-DX-A240-01A (aliquot TCGA-DX-A240-01A-32D-A27P-09) from TCGA case TCGA-DX-A240, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Spermatic cord; Age at diagnosis: 51.3 years (18,721 days).
Specimen TCGA-DX-A240-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ade8ee2e-19e0-410d-abe7-e0bcf0df6cdc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A240-10A (Blood Derived Normal), aliquot TCGA-DX-A240-10A-01D-A27P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46a9d407-3764-4b89-a1c2-377ef0e33f52

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 9, Silent 5, Frame Shift Del 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARL13B | c.74del p.L25* | Frame Shift Del (DEL) | VAF 17/42 reads (40%) | catalogued as rs1559971312; called by mutect2, pindel, varscan2
- ATP6V0A4 | c.420G>A p.T140= | Splice Region (SNP) | VAF 12/57 reads (21%) | catalogued as rs61747679, COSV100022999; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1846G>C p.V616L (on ENST00000361735 / NM_015935.5; = p.V530L on NM_014955.3) | Missense Mutation (SNP) | VAF 53/369 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as rs1558134145; called by muse, mutect2, varscan2
- SMARCC2 | c.1984C>T p.Q662* | Nonsense Mutation (SNP) | VAF 127/267 reads (48%) | catalogued as COSV57220112; called by muse, varscan2
- STAB1 | c.3411G>T p.L1137F | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as rs780601799; called by muse, mutect2, varscan2
- STIM2 | c.2131G>T p.A711S | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.078); catalogued as COSV99401908; called by muse, mutect2
- TMEM132B | c.1222G>A p.V408I | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.051); catalogued as rs554504714, COSV54760030; called by muse, mutect2, varscan2
- ZFYVE26 | c.6094C>A p.P2032T | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.395); catalogued as rs913291204; called by muse, mutect2, varscan2
- MED13 | c.4504C>G p.P1502A | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- RPAP3 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 32/832 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.511); called by muse, mutect2
- SLC4A7 | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMARCC2 | c.1586C>G p.S529C | Missense Mutation (SNP) | VAF 236/487 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ATAD5 | c.4824C>T p.D1608= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs375680809; called by muse, mutect2, varscan2
- CRP | c.393G>A p.G131= | Silent (SNP) | VAF 102/765 reads (13%) | called by muse, mutect2, varscan2
- DMD | c.8946A>G p.R2982= | Silent (SNP) | VAF 71/335 reads (21%) | called by muse, mutect2, varscan2
- HIC1 | c.1359C>T p.N453= (on ENST00000322941 / NM_001098202.1; = p.N434= on NM_006497.4) | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as rs1215299206; called by muse, mutect2, varscan2
- PLCH2 | c.339C>T p.D113= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs751401229, COSV53939163; called by muse, mutect2, varscan2
